Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A6E1, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A6E1-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT PELVIC LYMPH NODES:
METASTATIC ADENOCARCINOMA IN TWO OF SIXTEEN LYMPH NODES. (2/16). (SEE COMMENT)
- (B) LEFT PELVIC LYMPH NODES:
METASTATIC ADENOCARCINOMA IN THREE OF EIGHT LYMPH NODES. (3/8). (SEE COMMENT)
- (C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

COMMENT

The lymph nodes are extensively replaced by tumor (4.0 mm , 6.0 mm ,7.0 mm 7.0 mm and 7.0 mm foci). No extranodal extension is present.

GROSS DESCRIPTION

(A) RIGHT PELVIC LYMPH NODES – Received is a 5.5 x 5.0 x 2.0 cm aggregate of fibroadipose tissue. The specimen is dissected to reveal thirteen possible lymph nodes ranging from 0.1 up to 5.0 cm in greatest dimension. The specimen is submitted entirely.

SECTION CODE: A1, five possible lymph nodes; A2, three possible lymph nodes; A3, two possible lymph nodes; A4, one possible lymph node bisected; A5-A7, one possible lymph node serially sectioned; A8-A12, one possible lymph node serially sectioned; A13-A15, remainder of the specimen submitted entirely.

(B) LEFT PELVIC LYMPH NODES – Received is a 5.0 x 4.0 x 2.0 cm aggregate of fibroadipose tissue. The specimen is dissected to reveal nine possible lymph nodes ranging from 0.4 up to 3.5 cm in greatest dimension. The specimen is submitted entirely.

SECTION CODE: B1, four possible lymph nodes; B2, two possible lymph nodes; B3, one possible lymph node bisected; B4, B5, one possible lymph node bisected; B6, B7, one possible lymph node serially sectioned; B8-B10, remainder of the specimen submitted entirely.

(C) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

path ICD-O-3
Adenocarcinoma NOS 8140/3
Gleason
Adenocarcinoma, acinar 8140/3
Site Prostate NOS C61.9
JAJ 5/21/13

[page 2 of 4]
Page: 2

[REDACTED]
[REDACTED]
Specimen Date/Time:

Start of ADDENDUM

[page 3 of 4]
[REDACTED]
[REDACTED]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(C) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5). (SEE COMMENT)

Multifocal extraprostatic extension present.

TUMOR INVADING RIGHT AND LEFT SEMINAL VESICLES.

FOCAL EXTENSION OF TUMOR TO THE BASE (BLADDER NECK) MARGIN CANNOT BE EXCLUDED.
EXTENSIVE LYMPHOVASCULAR INVASION PRESENT.

SEE PREVIOUS REPORT FOR DIAGNOSIS OF PELVIC LYMPH NODES.

COMMENT

Approximately 90% of the prostate is occupied by prostatic adenocarcinoma. The tumor measures approximately 4.0 x 3.0 cm in the largest cross sectional dimension and it is present in the three cross sections of the prostate and extensively in the apex and base regions. The tumor exhibits multifocal extraprostatic extension. The tumor invades both seminal vesicles including intra and extraprostatic portions. In the base region, in the periurethral region, focal extension of tumor to the margin cannot be excluded. Additional sections were examined.

Please refer to the previous report for the diagnosis of the pelvic lymph nodes.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (6.0 x 4.2 x 3.7 cm, 53 grams, post fixation) has the usual shape. The soft tissue present along the left posterolateral aspect of the prostate appears more abundant than along the right side. The prostate is diffusely firm, particularly on the left side including the left seminal vesicle.

SECTION CODE: C1-C3, right seminal vesicle and segment of right vas deferens from the base towards the tip; C4-C8, left seminal vesicle and segment of left vas deferens from the base towards the tip; C9, C10, prostatic base, right border; C11-C15, prostatic base, right posterior border; C16-C23, prostatic base, central portion; C24, prostatic base, left border; C25-C27, prostatic base, left posterior border; C28-C30, apex anterior; C31, C32, apex left; C33-C37, apex posterior; C38-C40, apex right; C41, C42, detached portions of margin of resection according to specimen radiograph; C43-C55, sections of the four cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Orange ink (C45-C47, C50, C54 and C55) denotes surfaces that do not represent the true margin of resection.

SNOMED CODES

[REDACTED]

[page 4 of 4]
[REDACTED]
[REDACTED]
Specimen Date/Time:

Entire report and diagnosis completed by:

-----END OF REPORT-----

ITF/AA Discrepancy		

Source: NCI Genomic Data Commons file c4ad13a1-431d-40ef-859d-fc972043656e (TCGA-KK-A6E1.E8264E2D-E4BB-40BB-9305-18DDD777D664.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).